Somatic mutation profile of tumor specimen TCGA-G9-6498-01A (aliquot TCGA-G9-6498-01A-12D-A30X-08) from TCGA case TCGA-G9-6498, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 53.6 years (19,568 days).
Specimen TCGA-G9-6498-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7781a2eb-301f-456d-8344-73338e0d71d6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G9-6498-10A (Blood Derived Normal), aliquot TCGA-G9-6498-10A-01D-A30X-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a9a4be21-975e-4b31-aa06-f5d5a1eb54d1

The open-access MAF lists 29 somatic variants for this specimen: 21 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 19, Silent 8, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1526G>C p.G509A (on ENST00000288602 / NM_001374244.1; = p.G469A on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/121 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as rs121913355, CM060876, COSV56061424, COSV56062352, COSV56065622; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- ABCC12 | c.2530G>A p.A844T | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV60916016; called by mutect2, varscan2
- ARFGAP2 | c.113G>A p.S38N | Missense Mutation (SNP) | VAF 9/99 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54068010; called by muse, mutect2, varscan2
- EMSY | c.2305T>G p.S769A | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.112); catalogued as COSV58266325; called by muse, mutect2, varscan2
- ETNK1 | c.347G>A p.G116E | Missense Mutation (SNP) | VAF 28/146 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56884154, COSV56890004; called by muse, mutect2, varscan2
- FOXG1 | c.628T>C p.F210L | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV57399812; called by muse, mutect2, varscan2
- GJA1 | c.611C>T p.T204M | Missense Mutation (SNP) | VAF 14/174 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1270988821, COSV56997404, COSV56997732; called by muse, mutect2
- HTRA1 | c.1351G>A p.V451I | Missense Mutation (SNP) | VAF 56/203 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs149822364; called by muse, mutect2, varscan2
- LANCL1 | c.38A>G p.Y13C | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.497); catalogued as COSV52067295; called by muse, mutect2, varscan2
- OR4C46 | c.91G>A p.V31I | Missense Mutation (SNP) | VAF 24/151 reads (16%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.001); catalogued as rs746160836, COSV60221363; called by muse, mutect2, varscan2
- OR4D5 | c.71G>A p.R24Q | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.029); catalogued as rs778161914, COSV58309671; called by muse, mutect2, varscan2
- PIK3C2A | c.551C>T p.P184L | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.255); catalogued as COSV56407375, COSV99790549; called by muse, mutect2, varscan2
- PIK3CB | c.1451A>G p.Y484C | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.932); catalogued as rs1324578567, COSV56690576; called by muse, mutect2, varscan2
- RGS12 | c.1616C>T p.P539L | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.463); catalogued as rs760422329, COSV60910457; called by muse, mutect2, varscan2
- SLC16A6 | c.589G>A p.G197R | Missense Mutation (SNP) | VAF 4/69 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782713311, COSV59179569; called by muse, mutect2
- TRIM40 | c.73G>A p.V25M | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.488); catalogued as rs775056669, COSV57157860; called by muse, mutect2, varscan2
- USH2A | c.10339G>T p.A3447S | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT tolerated (0.51); PolyPhen benign (0.014); catalogued as COSV56388361; called by muse, mutect2
- AQP1 | c.508dup p.L170Pfs*16 | Frame Shift Ins (INS) | VAF 23/69 reads (33%) | called by mutect2, pindel, varscan2
- CCDC51 | c.130C>T p.P44S | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.034); called by muse, mutect2
- SNCAIP | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.197); called by muse, mutect2
- WDR11 | c.1991_1994del p.E664Vfs*34 | Frame Shift Del (DEL) | VAF 6/39 reads (15%) | called by mutect2, pindel
- CACNA1G | c.4557G>A p.S1519= | Silent (SNP) | VAF 13/106 reads (12%) | catalogued as rs370754259; called by muse, mutect2, varscan2
- CLEC11A | c.198T>G p.P66= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as COSV51575137; called by muse, mutect2, varscan2
- KLK5 | c.657T>C p.D219= | Silent (SNP) | VAF 10/68 reads (15%) | catalogued as COSV60451711; called by muse, mutect2, varscan2
- MAP3K5 | c.3171C>A p.I1057= | Silent (SNP) | VAF 49/155 reads (32%) | catalogued as COSV62892463; called by muse, mutect2, varscan2
- PCDHA2 | c.1452G>A p.A484= | Silent (SNP) | VAF 23/140 reads (16%) | catalogued as COSV65368508, COSV65371415; called by muse, mutect2, varscan2
- RBP3 | c.984G>C p.G328= | Silent (SNP) | VAF 8/43 reads (19%) | catalogued as rs145181839; called by muse, mutect2, varscan2
- RRM1 | c.423C>T p.F141= | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as COSV56166394; called by muse, mutect2, varscan2
- SMOC1 | c.708A>G p.E236= | Silent (SNP) | VAF 43/171 reads (25%) | catalogued as COSV62763512; called by muse, mutect2, varscan2
